Somatic mutation profile of tumor specimen TCGA-3E-AAAZ-01A (aliquot TCGA-3E-AAAZ-01A-11D-A38G-08) from TCGA case TCGA-3E-AAAZ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.8 years (26,234 days).
Specimen TCGA-3E-AAAZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97c31808-c531-49a0-957d-df318924c861.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3E-AAAZ-10A (Blood Derived Normal), aliquot TCGA-3E-AAAZ-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6d4e8e1-ab32-4d66-abe3-7e2b55784f75

The open-access MAF lists 52 somatic variants for this specimen: 44 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 7, Nonsense Mutation 5, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 60/354 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 60/401 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RNF43 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 154/748 reads (21%) | hotspot (GDC flag); catalogued as rs1458799446, COSV68456834; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 52/248 reads (21%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- SMAD4 | c.1052A>C p.D351A | Missense Mutation (SNP) | VAF 84/373 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685165, COSV61693805, COSV61696029; called by muse, mutect2, varscan2
- ANAPC7 | c.1385A>G p.K462R | Missense Mutation (SNP) | VAF 163/789 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV101482845; called by muse, mutect2, varscan2
- AOPEP | c.2301G>T p.R767S (on ENST00000375315 / NM_001193329.1; = p.R668S on NM_032823.5) | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs939421378, COSV99949083; called by muse, mutect2, varscan2
- AVPR1A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 157/791 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs1321821927, COSV54545511; called by muse, mutect2, varscan2
- BAALC | c.319G>A p.G107S (on ENST00000297574 / NM_001364874.1; = p.G72S on NM_024812.3) | Missense Mutation (SNP) | VAF 91/496 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99883281; called by muse, mutect2, varscan2
- BACH1 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 113/503 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99728035; called by muse, mutect2, varscan2
- BAHD1 | c.1897C>G p.L633V | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101346729; called by muse, mutect2, varscan2
- CACNA1B | c.6071C>T p.T2024M | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs1317101682, COSV53129778; called by muse, mutect2, varscan2
- CDC20B | c.989+2del p.X330_splice | Splice Site (DEL) | VAF 120/682 reads (18%) | catalogued as COSV99697547; called by mutect2, pindel, varscan2
- CDC73 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100813744; called by muse, mutect2, varscan2
- COL6A6 | c.5222G>A p.R1741H | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370927133; called by muse, mutect2, varscan2
- CPNE2 | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 83/511 reads (16%) | catalogued as COSV99321315; called by muse, mutect2, varscan2
- DLEC1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV100341742; called by muse, mutect2
- DNAH10 | c.5108C>T p.T1703M (on ENST00000409039; = p.T1642M on NM_207437.3) | Missense Mutation (SNP) | VAF 76/432 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs373004317; called by muse, mutect2, varscan2
- DTYMK | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 286/1440 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV99994716; called by muse, mutect2, varscan2
- FILIP1L | c.1315C>T p.Q439* (on ENST00000354552 / NM_182909.3; = p.Q199* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 109/637 reads (17%) | catalogued as COSV58776459; called by muse, mutect2, varscan2
- GPRC6A | c.2359G>A p.G787S | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.418); catalogued as COSV100114164; called by muse, mutect2, varscan2
- GREB1 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779065905, COSV52190944; called by muse, mutect2, varscan2
- GRM8 | c.1622G>C p.C541S | Missense Mutation (SNP) | VAF 80/427 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100281526; called by muse, mutect2, varscan2
- HROB | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 89/442 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV99809164; called by muse, mutect2, varscan2
- HS3ST6 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as rs371972747; called by muse, mutect2, varscan2
- HTR2C | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV52222439; called by muse, mutect2, varscan2
- IGSF22 | c.1116G>T p.K372N | Missense Mutation (SNP) | VAF 160/825 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100079338; called by muse, mutect2, varscan2
- IMPG2 | c.3088T>A p.W1030R | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99515066; called by muse, mutect2, varscan2
- LHX5 | c.423G>C p.L141F | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV99922413; called by muse, mutect2, varscan2
- LINGO1 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as rs757817349, COSV62438513; called by muse, mutect2
- NLRP3 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 175/480 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs145092553; called by muse, mutect2, varscan2
- NUAK2 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.691); catalogued as rs762199327, COSV100903995; called by muse, mutect2, varscan2
- PCDHA2 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 95/568 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV100973702; called by muse, mutect2, varscan2
- PDYN | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 97/541 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377075531, COSV54100958; called by muse, mutect2, varscan2
- PES1 | c.1126C>A p.Q376K | Missense Mutation (SNP) | VAF 119/607 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100073033; called by muse, mutect2, varscan2
- PTPN12 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 103/475 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99950175; called by muse, mutect2, varscan2
- SAMD15 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs974785526, COSV53627409; called by muse, mutect2, varscan2
- SEL1L2 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as COSV99532845; called by muse, mutect2
- THAP12 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 70/348 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99472821; called by muse, mutect2, varscan2
- TULP4 | c.2275G>A p.G759R | Missense Mutation (SNP) | VAF 51/863 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs760492393, COSV65581990; called by muse, mutect2
- ZNF382 | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53086373; called by muse, mutect2, varscan2
- ZNF585B | c.2285G>A p.S762N | Missense Mutation (SNP) | VAF 126/671 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100459349; called by muse, mutect2, varscan2
- ZNF688 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.186); catalogued as rs779204537, COSV99794121; called by muse, mutect2, varscan2
- CDC73 | c.973_999del p.X325_splice | Splice Site (DEL) | VAF 34/296 reads (11%) | called by mutect2, pindel
- CHL1 | c.3057C>T p.I1019= (on ENST00000397491 / NM_001253387.1; = p.I1035= on NM_006614.4) | Silent (SNP) | VAF 36/211 reads (17%) | catalogued as rs373156471, COSV99851023; called by muse, mutect2, varscan2
- COASY | c.342G>A p.V114= | Silent (SNP) | VAF 102/1130 reads (9%) | catalogued as COSV99888282; called by muse, mutect2
- FUOM | c.252C>T p.S84= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs780664461, COSV99529374; called by muse, varscan2
- MEGF6 | c.3984G>A p.G1328= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1557712687, COSV99619756; called by muse, mutect2
- MYO16 | c.3657C>T p.N1219= | Silent (SNP) | VAF 35/223 reads (16%) | catalogued as rs750792484, COSV62749419, COSV62764726; called by muse, mutect2, varscan2
- NLRP2 | c.1872G>A p.Q624= | Silent (SNP) | VAF 39/180 reads (22%) | catalogued as COSV99672012; called by muse, mutect2, varscan2
- NUDT19 | c.540G>C p.R180= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV101229192; called by muse, mutect2, varscan2
- OR1N2 | c.-39G>T | 5'UTR (SNP) | VAF 87/439 reads (20%) | catalogued as COSV101031358; called by muse, mutect2, varscan2
